Surgical pathology report (de-identified scan), TCGA case TCGA-39-5035, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5035-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

with CT C/A/P. Right lower lobe mass.

Specimens Submitted:

- 1: SP: Level seven mediastinal lymph nodes
- 2: SP: Level seven mediastinal lymph node #2
- 3: SP: Right pleural biopsy
- 4: SP: Right mediastinal lymph node level XI
- 5: SP: Right lower lobe lung

DIAGNOSIS:

- 1) LYMPH NODE, LEVEL VII MEDIASTINAL; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 2) LYMPH NODE, LEVEL VII MEDIASTINAL; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 3) PLEURA, RIGHT; BIOPSY:
- MESOTHELIAL-LINED FIBROCONNECTIVE TISSUE.
- 4) LYMPH NODE, RIGHT LEVEL XI MEDIASTINAL, EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 5) LUNG, RIGHT LOWER LOBE; LOBECTOMY:
- MODERATELY TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA OF RIGHT LOWER LOBE (SEE NOTE).
- THE TUMOR MEASURES 2.9 X 2.5 X 1.8 CM.
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE TUMOR EXTENDS SUBPLEURALLY BUT NOT TO THE PLEURAL SURFACE.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITIES: PLEURAL SCAR AND FOCAL ORGANIZING PNEUMONITIS.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): PERIBRONCHIAL: (0/3).

Note:

IMMUNOSTAINS PERFORMED ON THE TUMOR ARE AS FOLLOWS: 4A4 AND P63 POSITIVE;

** Continued on next page **

[page 2 of 4]
[REDACTED]

----- Page 2 of 4 -----
TFP-1, SYNAPTOPHYSIN, CHROMOGRANIN, AND MUCIN ARE NEGATIVE. THE PROFILE
SUPPORTS THE ABOVE DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
[REDACTED]

Special Studies:
Result [REDACTED]

[REDACTED]

1. The specimen is received fresh for frozen section consultation, labeled
"level 7 mediastinal lymph nodes" and consists of one lymph node measuring
1.1 x 0.7 x 0.5 cm. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section

[REDACTED]

2). The specimen is received fresh for frozen section consultation,
labeled "Level 7 mediastinal lymph node number two" and consists of a
red-tan oval piece of soft tissue measuring 0.9 x 0.4 x 0.3 cm. Entirely
submitted for frozen section.

Summary of sections:
FSC -- frozen section control

[REDACTED]

3). The specimen is received in formalin, labeled "Right pleural biopsy"
and consists of a piece of white tan soft and membranous tissue measuring
1.0 x 0.7 x 0.2 cm. At the surface, a 0.2 cm nodular area is noted the
specimen is bisected and submitted entirely.

Summary of sections:
U-undesignated

[REDACTED]

4). The specimen is received in formalin, labeled "right mediastinal lymph
node level 11 " and consists of three dark pink anthracotic lymph nodes
ranging in size from 0.5 to 1.0 cm in greatest dimension, which are entirely
submitted.

** Continued on next page **

[page 3 of 4]
Summary of sections:
U-undesignated

5). The specimen is received fresh and is labeled, "right lower lobe lung". It consists of a 14.3 x 14.2 x 6.4 cm lung lobe with attached bronchus and blood vessels straddled by multiple staple lines. The attached bronchus measures 0.9 cm. The pleural surface shows a 2.5 x 2.2 cm pleural scar with adhesions and a prior incision with sutures. The pleural surface is inked black. Serial sectioning reveals a 2.9 x 2.5 x 1.8 cm (remaining tumor) tan, stellate tumor abutting the pleural scar. The tumor is ill-defined, located 6.0 cm from the bronchial margin and 9.0 cm from the closest staple line. The tumor grossly does not involve the bronchus. A peribronchial anthracotic lymph node is identified and submitted. The uninvolved lung parenchyma is unremarkable. Representative sections are submitted. TPS is submitted photographs are taken.

Summary of sections:
BM -- bronchial margin.
VM -- vascular margin.
TP -- tumor with pleura.
TU -- tumor with adjacent pulmonary parenchyma.
RA - random lung parenchyma at least 3 cm away from main tumor
RC - random lung parenchyma close to tumor (within 3 cm of main tumor)
LN -- lymph node.

Summary of Sections:

Part 1: SP: Level seven mediastinal lymph nodes

Block	Sect.	Site	PCs
1		fsc	0

Part 2: SP: Level seven mediastinal lymph node #2

Block	Sect.	Site	PCs
1		fsc	1

Part 3: SP: Right pleural biopsy

Block	Sect.	Site	PCs
1		u	1

Part 4: SP: Right mediastinal lymph node level XI

Block	Sect.	Site	PCs
1		u	1

Part 5: SP: Right lower lobe lung

** Continued on next page **

[page 4 of 4]
Block	Sect. Site	PCs
1	BM	1
1	LN	1
3	RA	3
3	RC	3
2	TP	2
3	TU	3
1	VM	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: LEVEL SEVEN MEDIAST
LYMPH NODES : NEGATIVE LYMPH NODE.
PERMANENT DIAGNOSIS: SAME.

2. FROZEN SECTION DIAGNOSIS: SP: LEVEL SEVEN MEDIASTINAL
LYMPH NODE #2 : NEGATIVE LYMPH NODE.
PERMANENT DIAGNOSIS: SAME,

** End of Report **

Source: NCI Genomic Data Commons file 908dac9b-1244-48d6-90f6-5118bb82505e (TCGA-39-5035.65D294E9-BDDE-476E-8B45-DCEE87915A69.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).